Somatic mutation profile of tumor specimen TCGA-AS-3777-01A (aliquot TCGA-AS-3777-01A-01W-0886-08) from TCGA case TCGA-AS-3777, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.1 years (23,039 days).
Specimen TCGA-AS-3777-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c15c0fcb-20c5-43eb-b032-aa4da303f23d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AS-3777-10A (Blood Derived Normal), aliquot TCGA-AS-3777-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3d972e9-45ab-42b7-a82a-ece0ac38d018

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Splice Site 3, Frame Shift Ins 3, Nonsense Mutation 3, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 28/200 reads (14%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AHNAK | c.10446C>G p.F3482L | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV57216869; called by muse, mutect2, varscan2
- ARHGEF2 | c.1347G>A p.M449I (on ENST00000361247 / NM_001162383.2; = p.M421I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs774305439, COSV58112157; called by muse, mutect2, varscan2
- ARNT | c.955+1G>A p.X319_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV62231016; called by muse, mutect2
- ATP13A3 | c.2019C>A p.N673K | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55465594; called by muse, mutect2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 32/172 reads (19%) | catalogued as rs745882580; called by mutect2, varscan2
- BMX | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 12/330 reads (4%) | catalogued as COSV100564382, COSV59591793; called by muse, mutect2
- CD1A | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.175); catalogued as COSV56862312, COSV56863993; called by muse, mutect2
- CD8A | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV52157978; called by muse, mutect2
- CFAP47 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs1323139606, COSV52886160; called by muse, mutect2, varscan2
- DEFB116 | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 142/2114 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV68721963, COSV68722188; called by muse, mutect2
- DEPDC7 | c.748G>T p.D250Y (on ENST00000241051 / NM_001077242.2; = p.D241Y on NM_139160.2) | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53807331; called by muse, mutect2
- DIS3 | c.2593C>A p.P865T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66705657, COSV66706812; called by muse, mutect2, varscan2
- DSCAML1 | c.1228C>T p.R410C (on ENST00000321322; = p.R350C on NM_020693.4) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260152977, COSV58393365; called by muse, mutect2, varscan2
- FAM171A1 | c.2110C>T p.H704Y | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178951516, COSV65316909; called by muse, mutect2, varscan2
- ITGA5 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.725); catalogued as COSV53218494; called by muse, mutect2
- MAP2 | c.3832A>G p.K1278E | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52294947; called by muse, mutect2, varscan2
- MAPRE3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 23/764 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV51867619; called by muse, mutect2
- MAX | c.172-2A>G p.X58_splice | Splice Site (SNP) | VAF 17/92 reads (18%) | catalogued as COSV52417588, COSV52418923; called by muse, mutect2, varscan2
- MORC4 | c.1712A>C p.E571A | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55243326; called by muse, mutect2
- MT1H | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV60090973; called by muse, mutect2, varscan2
- MYO16 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201650171, COSV51782521; called by muse, mutect2, varscan2
- NUP205 | c.2500G>T p.A834S | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV53660758; called by muse, mutect2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 17/146 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- QPCT | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 70/114 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58120125; called by muse, mutect2, varscan2
- RMI2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 13/327 reads (4%) | catalogued as COSV56964150; called by muse, mutect2
- RNF40 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV61214225, COSV61215256; called by muse, mutect2
- SLC12A2 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52472490; called by muse, mutect2, varscan2
- SLC44A4 | c.462G>A p.W154* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV57667043; called by muse, mutect2, varscan2
- SNX25 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV53015461; called by muse, mutect2, varscan2
- SRL | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 132/540 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1234919281, COSV101281367, COSV68423607; called by muse, mutect2, varscan2
- TFRC | c.2277G>T p.E759D | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV64055116; called by muse, mutect2, varscan2
- USP54 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60443884; called by muse, mutect2, varscan2
- ADCK2 | c.912C>A p.N304K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- ECHS1 | c.800T>G p.F267C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SAGE1 | c.1724-33_1735del p.X575_splice | Splice Site (DEL) | VAF 26/252 reads (10%) | called by mutect2, pindel
- SCN1A | c.1336_1338del p.Q446del | In Frame Del (DEL) | VAF 40/98 reads (41%) | called by pindel, varscan2
- STEAP3 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by mutect2, varscan2
- TRANK1 | c.5439del p.F1813Lfs*12 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | called by mutect2, pindel, varscan2
- WDR77 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DPH7 | c.435G>A p.L145= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV53022517; called by muse, mutect2, varscan2
- EIF4G1 | c.744T>C p.P248= (on ENST00000346169 / NM_198241.3; = p.P52= on NM_004953.5) | Silent (SNP) | VAF 18/271 reads (7%) | catalogued as COSV59991631; called by muse, mutect2
- FREM2 | c.4330C>T p.L1444= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV54841052; called by muse, mutect2
- LARP1B | c.1680G>A p.K560= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV52798722; called by muse, mutect2
- NUP210L | c.2085G>A p.A695= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1050732640, COSV55149941, COSV99667285; called by muse, mutect2, varscan2
- PLA2R1 | c.852C>T p.S284= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV51780548; called by muse, mutect2
- RAB43 | c.96G>T p.T32= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV59349244; called by muse, mutect2, varscan2
- RETREG2 | c.664C>T p.L222= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV56087855; called by muse, mutect2
- TMX4 | c.318C>A p.T106= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV55681040; called by muse, mutect2, varscan2
- TSBP1 | c.1446A>G p.Q482= (on ENST00000617061; = p.Q487= on NM_006781.5) | Silent (SNP) | VAF 95/499 reads (19%) | catalogued as COSV66659535; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4735G>T | Intron (SNP) | VAF 55/107 reads (51%) | catalogued as COSV100447145; called by muse, mutect2, varscan2
